CGCI case BLGSP-71-19-00121 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5ef63b7d-8b09-47b3-af1e-d9d02cf5fd74

Demographics
Sex at birth: female; Race: black or african american; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. B cell lymphoma, NOS: ICD-O-3 morphology code: 9591/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: primary; Age at diagnosis: 3.4 years (1,233 days); Year of diagnosis: 2001; Method of diagnosis: Fine Needle Aspiration; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,874 days (16.1 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Other; Sites of involvement: Soft tissue / Sinus / Cerebrospinal fluid / Peritoneum, NOS / Small intestine / Ovary, NOS / Mediastinal soft tissue / Pleura / Colon, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 5,874 days (16.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- CD20: Positive.
- Lactate Dehydrogenase 6387 [Blood test normal range upper: 920].

Other clinical attributes
- Day 0: Weight: 18.1 kg; Height: 105 cm; BMI: 16.4.

Biospecimens (3 samples)
- Sample BLGSP-71-19-00121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Aspirate; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00121-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00121-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 172 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative.
- Primary pathology: Histologic diagnosis: Unclassifiable B-cell lymphoma; Extranodal site involvement: 10; Extranodal involvment other: pleural fluid and large bowel; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: aspiration of pleural fluid; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 6387.
- Tests performed, Genetic testing results, Genetic testing result: Immunophenotypic analysis tested: CD20.
